Somatic mutation profile of tumor specimen C3L-00791-01 (aliquot CPT0026410009) from CPTAC case C3L-00791, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 76.4 years (27,902 days).
Specimen C3L-00791-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 717834e8-b2d6-4c54-9215-4452b9d1f05c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00791-31 (Blood Derived Normal), aliquot CPT0029500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2885ce52-fc2e-4322-b65b-33e2fc99380d

The open-access MAF lists 90 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Intron 7, Frame Shift Del 5, Nonsense Mutation 3, RNA 2, In Frame Del 2, 5'Flank 2, 5'UTR 2, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC2 | c.2879G>T p.G960V | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100966684; called by muse, mutect2, varscan2
- AIP | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 114/343 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1380939691; called by muse, mutect2, varscan2
- ANKRD36B | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1310411445; called by muse, mutect2, varscan2
- ASTN1 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201600955, COSV56087176; called by muse, mutect2, varscan2
- ATAD2B | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 72/272 reads (26%) | catalogued as COSV53197278; called by muse, mutect2, varscan2
- B3GNT8 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs144748764, COSV54197039; called by muse, varscan2
- HS3ST3A1 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 86/567 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV52375285; called by muse, mutect2, varscan2
- LMBR1 | c.759G>A p.G253= | Splice Region (SNP) | VAF 15/53 reads (28%) | catalogued as rs747964556; called by muse, mutect2, varscan2
- MEGF10 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.318); catalogued as rs754091432, COSV57244268, COSV99175120; called by muse, mutect2, varscan2
- PDPN | c.412G>T p.V138F (on ENST00000621990; = p.V214F on NM_006474.4) | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53849414; called by muse, varscan2
- SLC12A3 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as CM088285; called by muse, mutect2, varscan2
- STAMBPL1 | c.1205G>T p.C402F | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs899092176; called by mutect2, varscan2
- TAX1BP1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 138/492 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.179); catalogued as rs748509003, COSV55291617, COSV55295565; called by muse, mutect2, varscan2
- TNFRSF4 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs777266991; called by muse, mutect2, varscan2
- ZFP69B | c.961T>C p.S321P | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1341590636; called by muse, mutect2, varscan2
- ZNF614 | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374687937; called by muse, mutect2, varscan2
- ACTB | c.599T>A p.F200Y | Missense Mutation (SNP) | VAF 151/537 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ANK1 | c.3599G>A p.C1200Y | Missense Mutation (SNP) | VAF 190/566 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ARHGAP32 | c.1313A>G p.D438G (on ENST00000310343 / NM_001378025.1; = p.D89G on NM_014715.4) | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1S | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CANX | c.387T>A p.H129Q | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, varscan2
- CNTNAP1 | c.4034del p.P1345Lfs*134 | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | called by mutect2, pindel, varscan2
- CPED1 | c.2636A>G p.E879G | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- DLX2 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DNMBP | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FAT4 | c.5454T>G p.D1818E | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- GNE | c.1514C>T p.T505I (on ENST00000396594 / NM_001128227.3; = p.T474I on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/503 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- HEXIM1 | c.1013A>G p.Q338R | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HS3ST3B1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- IL2RG | c.772T>G p.F258V | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- KLHL29 | c.1213A>T p.K405* | Nonsense Mutation (SNP) | VAF 180/579 reads (31%) | called by muse, mutect2, varscan2
- LRRC70 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- MACF1 | c.17036C>T p.A5679V (on ENST00000372915; = p.A3721V on NM_012090.5) | Missense Mutation (SNP) | VAF 60/170 reads (35%) | called by muse, mutect2, varscan2
- MAN2A1 | c.3331C>T p.P1111S | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- NFE2L1 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OAT | c.343_351del p.F115_N117del | In Frame Del (DEL) | VAF 88/265 reads (33%) | called by mutect2, pindel, varscan2
- OPTN | c.4T>A p.S2T | Missense Mutation (SNP) | VAF 117/429 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- OR2B6 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSR1 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PBRM1 | c.2472_2473delinsTTGACATATT p.I825* | Nonsense Mutation (INS) | VAF 38/109 reads (35%) | called by pindel, varscan2*
- POFUT2 | c.693del p.E232Nfs*43 | Frame Shift Del (DEL) | VAF 77/287 reads (27%) | called by mutect2, pindel, varscan2
- RAI1 | c.4961G>T p.G1654V | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RPS6KA4 | c.1779G>T p.W593C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SDK2 | c.4199C>T p.P1400L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SETD2 | c.4898C>G p.P1633R | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIPA1 | c.2258A>C p.K753T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SIPA1L2 | c.3021G>C p.M1007I | Missense Mutation (SNP) | VAF 105/296 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SURF2 | c.629C>G p.T210S | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SVEP1 | c.8303C>G p.P2768R | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNGAP1 | c.3167G>T p.G1056V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TDRD15 | c.4312A>T p.T1438S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TMPRSS11D | c.930_932del p.W311del | In Frame Del (DEL) | VAF 38/119 reads (32%) | called by mutect2, pindel, varscan2
- TNNT1 | c.70del p.E24Kfs*27 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | called by mutect2, pindel, varscan2
- TNRC18 | c.6756C>A p.D2252E | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- VHL | c.271_283del p.F91Rfs*64 | Frame Shift Del (DEL) | VAF 87/243 reads (36%) | called by mutect2, pindel, varscan2
- XPO5 | c.529del p.D177Tfs*6 | Frame Shift Del (DEL) | VAF 36/141 reads (26%) | called by mutect2, pindel, varscan2
- ZCCHC17 | c.317+5_317+8del p.X106_splice | Splice Site (DEL) | VAF 28/98 reads (29%) | called by pindel, varscan2
- ZNF211 | c.1302T>G p.F434L (on ENST00000347302 / NM_198855.4; = p.F447L on NM_006385.5) | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF468 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ZXDC | c.245C>A p.P82Q | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ASPH | c.2181A>G p.V727= | Silent (SNP) | VAF 57/171 reads (33%) | catalogued as rs1437566719; called by muse, mutect2, varscan2
- C8orf34 | c.135A>G p.A45= | Silent (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- CCDC28A | c.219G>T p.P73= | Silent (SNP) | VAF 74/262 reads (28%) | called by muse, mutect2, varscan2
- CRYBG2 | c.3150C>T p.T1050= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as rs759764606, COSV100366316; called by muse, mutect2, varscan2
- ITGB6 | c.315G>T p.A105= | Silent (SNP) | VAF 46/189 reads (24%) | catalogued as rs140575384; called by muse, mutect2, varscan2
- LRRC37A3 | c.753G>A p.E251= | Silent (SNP) | VAF 54/760 reads (7%) | called by muse, varscan2
- MAP11 | c.648G>A p.L216= | Silent (SNP) | VAF 66/193 reads (34%) | catalogued as rs1562952809; called by muse, mutect2, varscan2
- MYO16 | c.4470G>T p.P1490= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV100696345; called by muse, mutect2, varscan2
- PDCD2L | c.822C>T p.L274= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as rs1463494533, COSV55824961, COSV55825245; called by muse, mutect2, varscan2
- PKD1L1 | c.642G>A p.T214= | Silent (SNP) | VAF 122/377 reads (32%) | catalogued as rs577610499; called by muse, mutect2, varscan2
- SLC35F6 | c.927A>G p.A309= | Silent (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- SOX17 | c.918C>T p.G306= | Silent (SNP) | VAF 60/161 reads (37%) | catalogued as rs1483221878; called by muse, mutect2, varscan2
- TTC22 | c.1671C>T p.G557= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs1227990233; called by muse, mutect2, varscan2
- TULP4 | c.2112G>A p.T704= | Silent (SNP) | VAF 78/168 reads (46%) | catalogued as rs922327441, COSV100893912; called by muse, mutect2, varscan2
- VPS72 | c.69A>G p.A23= | Silent (SNP) | VAF 46/241 reads (19%) | called by muse, mutect2, varscan2
- ZNF407 | c.2061G>A p.L687= | Silent (SNP) | VAF 32/167 reads (19%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3208del | Intron (DEL) | VAF 81/306 reads (26%) | called by mutect2, pindel, varscan2
- CRY2 | chr11:45847468 T>G | 5'Flank (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- DBP | c.550+82G>T | Intron (SNP) | VAF 48/148 reads (32%) | called by muse, mutect2, varscan2
- DMTN | c.-50C>T | 5'UTR (SNP) | VAF 33/98 reads (34%) | catalogued as rs1308135169; called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1795G>T | RNA (SNP) | VAF 45/284 reads (16%) | called by muse, mutect2, varscan2
- HPN | c.-597T>G | 5'UTR (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- IFT80 | c.777+12270A>T | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, varscan2
- MIR30C2 | chr6:71377034 C>T | 5'Flank (SNP) | VAF 41/114 reads (36%) | catalogued as rs766298631; called by muse, mutect2, varscan2
- PIGQ | c.1531+318C>T | Intron (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- PLIN1 | c.*18_*37del | 3'UTR (DEL) | VAF 35/113 reads (31%) | called by mutect2, pindel, varscan2
- RRM2 | n.423T>C | RNA (SNP) | VAF 61/256 reads (24%) | called by muse, mutect2, varscan2
- TCF4 | c.1070-31G>T | Intron (SNP) | VAF 84/305 reads (28%) | called by muse, mutect2, varscan2
- ZNF419 | c.199+27A>T | Intron (SNP) | VAF 73/229 reads (32%) | called by muse, mutect2, varscan2
- ZNF665 | c.-54+10415T>G | Intron (SNP) | VAF 99/347 reads (29%) | called by muse, mutect2, varscan2
